Somatic mutation profile of tumor specimen TCGA-AR-A5QM-01A (aliquot TCGA-AR-A5QM-01A-11D-A27P-09) from TCGA case TCGA-AR-A5QM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.4 years (22,780 days).
Specimen TCGA-AR-A5QM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c03db44e-b4c3-4d95-831c-b160bca7d5f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A5QM-10A (Blood Derived Normal), aliquot TCGA-AR-A5QM-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c86368c-5c5a-463d-95b2-7c359907f51f

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 2, Nonsense Mutation 2, Intron 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs876658932, COSV55732282, COSV55739285; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALX4 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747909089, COSV61327684; called by muse, mutect2, varscan2
- ERN2 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314821507, COSV55624262; called by muse, mutect2, varscan2
- FBP1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100941247; called by muse, mutect2
- FBXO43 | c.2018G>A p.C673Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV71055515; called by muse, mutect2, varscan2
- HIRIP3 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs770674805, COSV99663121; called by muse, mutect2
- MRPS12 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV99671382; called by muse, mutect2
- OGDH | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56056835; called by muse, mutect2, varscan2
- RASGRP4 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.906); catalogued as COSV53038036, COSV53039783; called by muse, mutect2, varscan2
- RNPS1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV57046814; called by muse, mutect2, varscan2
- SAMSN1 | c.279G>A p.K93= | Splice Region (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99581646; called by muse, mutect2
- SEMA4B | c.1873A>C p.N625H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); catalogued as COSV60175861; called by muse, mutect2, varscan2
- SLITRK2 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59428537; called by muse, mutect2, varscan2
- TEX15 | c.1620C>A p.N540K (on ENST00000256246; = p.N923K on NM_001350162.2) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV56353505; called by muse, mutect2, varscan2
- THSD7B | c.4745G>A p.C1582Y (on ENST00000272643; = p.C1580Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55736225; called by muse, mutect2, varscan2
- TMEM132E | c.1434C>A p.S478R (on ENST00000321639; = p.S568R on NM_001304438.2) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58695951, COSV58700452; called by muse, mutect2, varscan2
- TMEM185A | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57560562; called by muse, mutect2, varscan2
- TNS4 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV54188014; called by muse, mutect2, varscan2
- ZNF280C | c.763C>A p.H255N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63969929; called by muse, mutect2, varscan2
- ZNF99 | c.2036G>T p.C679F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68056724; called by muse, mutect2, varscan2
- ANKRD12 | c.938dup p.Y313* | Nonsense Mutation (INS) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- SLC4A1 | c.2625G>A p.P875= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs202243808, COSV52263061; called by muse, mutect2, varscan2
- TFAP2D | c.417C>A p.A139= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV50454464; called by muse, mutect2, varscan2
- BRWD1 | c.6571+21A>G | Intron (SNP) | VAF 9/74 reads (12%) | catalogued as rs768563077, COSV60902661; called by muse, mutect2, varscan2
- MAGEC3 | c.1728+50T>A | Intron (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100025387, COSV68924315; called by muse, mutect2, varscan2
- SPATA8 | n.867C>T | RNA (SNP) | VAF 23/63 reads (37%) | catalogued as rs150122584, COSV60705548; called by muse, mutect2, varscan2
